Gene-level copy-number profile of tumor specimen TCGA-33-4583-01A from TCGA case TCGA-33-4583, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.4 years (26,799 days).
Specimen TCGA-33-4583-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4513b9b7-3ac2-4c24-aff0-783d2657d368.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4583-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f677f51a-1c5a-4567-bd3b-7fc2cad40cf8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 2: 12,007; copy number 3: 16,235; copy number 4: 20,436; copy number 5: 5,154; copy number 6: 2,710; copy number 7: 3,071; copy number 8: 70; copy number 9: 2; copy number 10: 100.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4583-01A-01D-1439-01): tumor purity 0.52, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:54,918,231–54,967,088, 1 gene: LRTM1.
- chr4:163,524,298–164,384,050, 1 gene (within-gene range 0–2): MARCHF1.
- chr4:163,828,800–164,190,367, 3 genes: RN7SKP105, YWHAQP4, AC105250.1.
- chr10:21,524,646–21,743,630, 1 gene (within-gene range 0–3): MLLT10.
- chr10:21,564,471–22,003,769, 6 genes (within-gene range 0–3): RNU6-306P, HNRNPRP1, RNU6-1141P, DNAJC1, RN7SKP219, AL359697.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 102 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:27,638,483–27,646,483, 2 genes, copy number 9: ERVK-28, AC112702.1.
- chr20:28,563,850–32,809,356, 100 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
